Somatic mutation profile of tumor specimen MMRF_2819_1_BM_CD138pos (aliquot MMRF_2819_1_BM_CD138pos_T1_KHS5U_L15705) from MMRF case MMRF_2819, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,652 days).
Specimen MMRF_2819_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6546b76b-2a56-4897-9984-3fe8d04565bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2819_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2819_1_PB_WBC_C2_KHS5U_L15751; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a30aec-a716-425e-88d6-9e30fabd7431

The open-access MAF lists 68 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 15, Silent 11, Intron 9, Splice Site 2, 5'Flank 2, 5'UTR 2, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 92/214 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 165/503 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARL6IP4 | c.1132C>T p.R378C (on ENST00000315580 / NM_018694.3; = p.R359C on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs745538478, COSV54903158; called by muse, mutect2, varscan2
- COL11A1 | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62171610; called by muse, mutect2, varscan2
- EEA1 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100467999; called by muse, mutect2, varscan2
- FAM83E | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1258861491; called by muse, mutect2, varscan2
- IGHV3-7 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 100/138 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as rs570873924; called by muse, varscan2
- IGHV3-7 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 130/159 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs181058459; called by muse, varscan2
- JCAD | c.2835C>G p.F945L | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs775621147; called by muse, mutect2, varscan2
- KCTD18 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs933969594, COSV63344576, COSV63345157; called by muse, mutect2
- PIK3C2G | c.959A>T p.H320L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99850717; called by muse, mutect2, varscan2
- SEMA5A | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs755630996, COSV101228239; called by muse, mutect2, varscan2
- SGSM1 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1213747534, COSV68510263; called by muse, mutect2, varscan2
- SLC2A3 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs777199710, COSV50004008, COSV50006458; called by muse, varscan2
- SRCAP | c.6763C>T p.R2255C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs765300730; called by muse, mutect2, varscan2
- TENT5B | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 196/432 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1210894410; called by muse, mutect2, varscan2
- ABHD17B | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ALAD | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ARID2 | c.5369_5372del p.L1790* | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.1529T>A p.L510H | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB1 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- C1orf35 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CAST | c.717C>G p.F239L (on ENST00000341926; = p.F322L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNT1 | c.1366dup p.D456Gfs*16 | Frame Shift Ins (INS) | VAF 30/330 reads (9%) | called by mutect2, pindel
- DOCK10 | c.2283G>C p.L761F | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCF11 | c.192+2T>G p.X64_splice | Splice Site (SNP) | VAF 84/210 reads (40%) | called by muse, mutect2, varscan2
- WDFY4 | c.6664-12_6664-1del p.X2222_splice | Splice Site (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- ZNF839 | c.2030C>T p.T677I (on ENST00000558850 / NM_001267827.1; = p.T793I on NM_018335.5) | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.141); called by muse, mutect2
- B4GALNT2 | c.1680C>T p.N560= | Silent (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- CPED1 | c.117G>A p.R39= | Silent (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- CRIM1 | c.2076G>A p.T692= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as rs912260044; called by muse, mutect2, varscan2
- GCN1 | c.3390C>A p.L1130= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- GRB14 | c.1092C>T p.S364= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2
- GREB1L | c.3486C>T p.S1162= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- KRT15 | c.453C>T p.C151= | Silent (SNP) | VAF 69/163 reads (42%) | catalogued as rs375944757; called by muse, mutect2, varscan2
- SLIT1 | c.4350C>T p.G1450= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs141751619; called by muse, mutect2, varscan2
- VANGL2 | c.6C>T p.D2= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- VMP1 | c.1134C>T p.Y378= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs200690423; called by muse, mutect2, varscan2
- WNT11 | c.642G>T p.V214= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2
- ATP8A2 | c.*4155C>A | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- CD44 | c.1283-88A>C | Intron (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2
- ERLIN2 | c.*2066T>A | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- FKBP7 | c.374-3339T>C | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- GSTK1 | c.384+34A>T | Intron (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- HCFC1 | c.*1069G>A | 3'UTR (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- KCNK10 | c.-197C>T | 5'UTR (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- KLF6 | c.*2410dup | 3'UTR (INS) | VAF 29/87 reads (33%) | catalogued as rs768488009; called by mutect2, pindel, varscan2
- MEIS1 | c.1024+90A>G | Intron (SNP) | VAF 51/243 reads (21%) | called by muse, mutect2, varscan2
- MID1IP1 | c.*759A>T | 3'UTR (SNP) | VAF 28/34 reads (82%) | called by muse, mutect2, varscan2
- NABP1 | c.*1994T>C | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- NEDD9 | c.*770G>A | 3'UTR (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- NOX4 | chr11:89491521 C>T | 5'Flank (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2
- OGT | c.*1492G>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- PATJ | c.*377A>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- PINLYP | c.*48G>C | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*185T>C | 3'UTR (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- PRRC2C | c.-57-110_-57-108del | Intron (DEL) | VAF 20/41 reads (49%) | called by mutect2, pindel, varscan2
- SAMD13 | c.113+35A>C | Intron (SNP) | VAF 153/377 reads (41%) | called by muse, mutect2, varscan2
- SERP1 | c.160+157T>G | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- SLC5A12 | c.*2235C>T | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- SLC66A3 | c.*485A>G | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627737 C>A | 3'Flank (SNP) | VAF 19/24 reads (79%) | called by muse, mutect2, varscan2
- TET3 | c.304-395T>G | Intron (SNP) | VAF 9/13 reads (69%) | catalogued as rs982264773; called by muse, mutect2, varscan2
- TMEM19 | c.-404C>T | 5'UTR (SNP) | VAF 80/185 reads (43%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331277 G>A | 5'Flank (SNP) | VAF 43/84 reads (51%) | catalogued as rs529802001; called by muse, mutect2, varscan2
- UXS1 | c.969+176G>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- WNT7B | c.*1901G>A | 3'UTR (SNP) | VAF 91/217 reads (42%) | called by muse, mutect2, varscan2
- ZNF174 | c.*176G>A | 3'UTR (SNP) | VAF 48/113 reads (42%) | catalogued as rs1334303161; called by muse, mutect2, varscan2
